Somatic mutation profile of tumor specimen TCGA-BP-5174-01A (aliquot TCGA-BP-5174-01A-01D-1429-08) from TCGA case TCGA-BP-5174, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 45.7 years (16,693 days).
Specimen TCGA-BP-5174-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a62a2892-0c8a-49be-b6c3-93b4b9fc30a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5174-11A (Solid Tissue Normal), aliquot TCGA-BP-5174-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31cfab6c-a267-44ed-94e7-b0a05dcbf224

The open-access MAF lists 40 somatic variants for this specimen: 34 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Frame Shift Del 7, Silent 5, Splice Region 1, Splice Site 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM2A | c.1212dup p.G405Rfs*48 (on ENST00000219054; = p.G326Rfs*48 on NM_001308169.2) | Frame Shift Ins (INS) | VAF 51/210 reads (24%) | catalogued as rs755296455; called by mutect2, pindel, varscan2
- ADIG | c.174C>A p.S58R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.801); catalogued as rs746283465, COSV64893740; called by muse, mutect2, varscan2
- AKR1B15 | c.855T>G p.N285K | Missense Mutation (SNP) | VAF 67/219 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.465); catalogued as rs375543873, COSV71152134; called by muse, mutect2, varscan2
- DISC1 | c.167T>A p.F56Y | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV54409685; called by muse, mutect2, varscan2
- DNAJC10 | c.887C>T p.T296I | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1355831387, COSV51139954; called by muse, mutect2, varscan2
- DPYS | c.674T>C p.V225A | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.867); catalogued as COSV60909846; called by muse, mutect2, varscan2
- ELK3 | c.257C>A p.S86Y | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV57386905; called by muse, mutect2, varscan2
- FAT4 | c.5465C>T p.S1822F | Missense Mutation (SNP) | VAF 85/308 reads (28%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as COSV58673396; called by muse, mutect2, varscan2
- KIAA1549L | c.2407C>T p.P803S (on ENST00000321505; = p.P1100S on NM_012194.3) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV55775487; called by muse, mutect2, varscan2
- MFAP2 | c.120C>G p.D40E | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV65003852; called by muse, mutect2, varscan2
- MINDY3 | c.536T>C p.F179S | Missense Mutation (SNP) | VAF 82/353 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV53221364; called by muse, mutect2, varscan2
- MYH7 | c.2423+2T>A p.X808_splice | Splice Site (SNP) | VAF 30/97 reads (31%) | catalogued as rs111726379, COSV62520405; called by muse, mutect2, varscan2
- ORC4 | c.1125T>A p.A375= | Splice Region (SNP) | VAF 50/256 reads (20%) | catalogued as COSV51574430; called by muse, mutect2, varscan2
- PIGK | c.653C>A p.P218H | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63062425; called by muse, mutect2, varscan2
- PKD1L1 | c.6732A>C p.E2244D | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.236); catalogued as COSV56968016; called by muse, mutect2, varscan2
- PTPRN2 | c.1861G>C p.V621L | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV67043246; called by muse, mutect2, varscan2
- RSPH9 | c.172T>C p.Y58H | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1295090908, COSV64665083; called by muse, mutect2, varscan2
- SASS6 | c.1475C>A p.P492H | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.163); catalogued as COSV54928400; called by muse, mutect2, varscan2
- SH3TC1 | c.540G>T p.L180F | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as COSV55285493; called by muse, mutect2, varscan2
- SLC22A16 | c.1153G>A p.G385S | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV57930882; called by muse, mutect2, varscan2
- SLC35A4 | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV60051422, COSV60052845; called by muse, mutect2, varscan2
- SMC5 | c.919A>C p.T307P | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.894); catalogued as COSV63193553; called by muse, mutect2
- SNX14 | c.857T>C p.L286P (on ENST00000314673 / NM_001350535.1; = p.L242P on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV59013249; called by muse, mutect2, varscan2
- STPG2 | c.728G>A p.S243N | Missense Mutation (SNP) | VAF 115/398 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV54797689; called by muse, mutect2, varscan2
- TACR3 | c.1075C>A p.L359M | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV59202940; called by muse, mutect2, varscan2
- TEKT4 | c.118C>A p.L40M | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.77); catalogued as COSV54625831; called by muse, mutect2, varscan2
- TRAT1 | c.388C>A p.H130N | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55468946, COSV55469125; called by muse, mutect2, varscan2
- ADCY7 | c.2321del p.L774Rfs*22 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | called by mutect2, pindel, varscan2
- KLHL17 | c.192_201del p.H65Pfs*15 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, pindel
- OR7A17 | c.647_653del p.C216Sfs*4 | Frame Shift Del (DEL) | VAF 27/175 reads (15%) | called by mutect2, pindel, varscan2
- SPATA4 | c.122_136delinsCTAA p.V41Afs*50 | Frame Shift Del (DEL) | VAF 23/121 reads (19%) | called by pindel, varscan2*
- TMEM168 | c.1422del p.F474Lfs*8 | Frame Shift Del (DEL) | VAF 34/154 reads (22%) | called by mutect2, pindel, varscan2
- UGT1A3 | c.822_828del p.F275Gfs*90 | Frame Shift Del (DEL) | VAF 41/315 reads (13%) | called by mutect2, pindel
- VHL | c.347_363delinsA p.L116Qfs*38 | Frame Shift Del (DEL) | VAF 66/233 reads (28%) | called by pindel, varscan2*
- APBA1 | c.930C>T p.R310= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV55230072; called by muse, mutect2
- DHX36 | c.936A>T p.T312= | Silent (SNP) | VAF 39/132 reads (30%) | catalogued as COSV57673881; called by muse, mutect2, varscan2
- DSCAM | c.5901C>T p.A1967= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs772161625, COSV68021646, COSV68030295; called by muse, mutect2, varscan2
- GRHL3 | c.1002C>G p.A334= (on ENST00000350501 / NM_198174.3; = p.A339= on NM_021180.3) | Silent (SNP) | VAF 88/485 reads (18%) | catalogued as COSV52567755; called by muse, mutect2, varscan2
- RBM28 | c.150C>T p.V50= | Silent (SNP) | VAF 37/123 reads (30%) | catalogued as COSV56163454; called by muse, mutect2, varscan2
- MLX | c.*1C>T | 3'UTR (SNP) | VAF 72/271 reads (27%) | catalogued as COSV99518979; called by muse, mutect2, varscan2
